CCDI case PBBZUK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8d44a808-52ed-46c6-b9a6-a5888c0ba0f1

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.4 years (4,159 days).

Biospecimens (3 samples)
- Sample 0DM4X2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DM4XR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DM4XU: Tissue type: Tumor; Specimen type: Solid Tissue.
